Somatic mutation profile of tumor specimen HCM-BROD-0650-C56-06A (aliquot HCM-BROD-0650-C56-06A-01D-A881-36) from HCMI case HCM-BROD-0650-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; Tumor grade: High Grade; Age at diagnosis: 67.2 years (24,542 days).
Specimen HCM-BROD-0650-C56-06A: Sample type: Human Tumor Original Cells; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Human Original Cells; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) caa78137-ea31-490d-b627-d70c03406f49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0650-C56-12A (Saliva), aliquot HCM-BROD-0650-C56-12A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7934f65b-b341-4c2b-9a33-59de465258c5

The open-access MAF lists 172 somatic variants for this specimen: 133 protein-altering or splice-affecting, 34 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 119, Silent 34, Nonsense Mutation 7, Intron 4, Frame Shift Ins 2, In Frame Del 2, Splice Site 1, 3'UTR 1, Frame Shift Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN1A | c.4282G>T p.V1428F (on ENST00000303395 / NM_001202435.3; = p.V1417F on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/222 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs878854263; ClinVar: pathogenic; called by muse, varscan2
- ANKS1B | c.2017A>T p.I673F | Missense Mutation (SNP) | VAF 36/606 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV61349555, COSV61368911; called by muse, mutect2
- APOB | c.8245A>G p.T2749A | Missense Mutation (SNP) | VAF 159/572 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs1429563329, COSV99266420; called by muse, mutect2, varscan2
- ARHGAP42 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 22/542 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs1565284108; called by muse, mutect2
- ATP10A | c.3545G>A p.S1182N | Missense Mutation (SNP) | VAF 164/540 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs564882602; called by muse, mutect2, varscan2
- ATP1A3 | c.1162C>T p.R388C (on ENST00000545399 / NM_001256214.2; = p.R375C on NM_152296.5) | Missense Mutation (SNP) | VAF 324/531 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs1057524683, COSV57488873; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAG4 | c.949A>T p.S317C | Missense Mutation (SNP) | VAF 28/674 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as COSV54860708; called by muse, mutect2
- BPTF | c.418_447del p.M140_D149del | In Frame Del (DEL) | VAF 347/496 reads (70%) | catalogued as rs759306365; called by mutect2, varscan2
- CASP8 | c.193C>G p.L65V | Missense Mutation (SNP) | VAF 96/398 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs747668924; called by muse, mutect2, varscan2
- CBX7 | c.126G>A p.W42* | Nonsense Mutation (SNP) | VAF 8/194 reads (4%) | catalogued as COSV99334108; called by muse, mutect2
- CCER1 | c.86C>T p.S29L | Missense Mutation (SNP) | VAF 266/902 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.438); catalogued as rs1211501476; called by muse, mutect2, varscan2
- CFAP46 | c.3100G>A p.A1034T | Missense Mutation (SNP) | VAF 206/510 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs777460078; called by muse, mutect2, varscan2
- CFAP47 | c.9518G>A p.G3173E | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1395924702; called by muse, mutect2, varscan2
- CYC1 | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 159/646 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1371182397, COSV59644447; called by muse, mutect2, varscan2
- CYP11B2 | c.1235G>C p.R412P | Missense Mutation (SNP) | VAF 404/658 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs780112807, COSV59995495; called by muse, mutect2, varscan2
- DDI1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 228/759 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs779548652, COSV56371148; called by muse, mutect2, varscan2
- DNAAF5 | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 170/374 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs779352236, COSV52414902; called by muse, mutect2, varscan2
- ELOVL7 | c.736A>G p.S246G | Missense Mutation (SNP) | VAF 169/371 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781379671; called by muse, mutect2, varscan2
- EMILIN1 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 175/568 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1278526194, COSV66694838; called by muse, mutect2, varscan2
- FBN1 | c.4894C>T p.R1632C | Missense Mutation (SNP) | VAF 125/337 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs544990350; called by muse, mutect2, varscan2
- FMOD | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 154/629 reads (24%) | catalogued as COSV61610479; called by muse, mutect2, varscan2
- GRHL2 | c.1288C>T p.R430W | Missense Mutation (SNP) | VAF 32/465 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1456445530; called by muse, mutect2
- HGD | c.1252T>G p.C418G | Missense Mutation (SNP) | VAF 184/705 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV52198574; called by muse, mutect2, varscan2
- IFIH1 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 50/585 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs372313271; called by muse, mutect2
- IL13RA2 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781815956; called by muse, mutect2, varscan2
- KCNJ15 | c.693C>A p.N231K | Missense Mutation (SNP) | VAF 140/416 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as COSV60811219; called by muse, varscan2
- LARP1B | c.1174G>C p.V392L | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1445124526; called by muse, varscan2
- MAGEB2 | c.687G>T p.M229I | Missense Mutation (SNP) | VAF 183/241 reads (76%) | SIFT tolerated (0.34); PolyPhen benign (0.036); catalogued as rs1391671203, COSV100975752; called by muse, mutect2, varscan2
- MARF1 | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 93/663 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.207); catalogued as COSV60024872; called by muse, mutect2, varscan2
- MUC5B | c.11146C>T p.P3716S | Missense Mutation (SNP) | VAF 54/758 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs565982586; called by muse, mutect2
- MYB | c.791C>T p.A264V | Missense Mutation (SNP) | VAF 34/251 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as COSV100214866; called by muse, mutect2, varscan2
- NF2 | c.576C>A p.Y192* | Nonsense Mutation (SNP) | VAF 180/222 reads (81%) | catalogued as CM994608, COSV100097796, COSV58520186, COSV58532890; called by mutect2, varscan2
- NRXN3 | c.2366A>G p.K789R (on ENST00000335750 / NM_001330195.2; = p.K416R on NM_004796.6) | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.966); catalogued as COSV100200419; called by muse, mutect2
- PGBD5 | c.1285G>C p.V429L (on ENST00000525115; = p.V498L on NM_001258311.2) | Missense Mutation (SNP) | VAF 164/497 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.091); catalogued as rs148414368, COSV58412934; called by muse, mutect2, varscan2
- PNLIPRP1 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 210/653 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs116575931, COSV100724521, COSV62613062; called by muse, mutect2, varscan2
- RAD51AP2 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 54/590 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.181); catalogued as rs1341118226; called by muse, mutect2
- RPTN | c.982A>C p.S328R | Missense Mutation (SNP) | VAF 88/832 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV60166831; called by muse, mutect2
- SAMD9 | c.2765C>T p.A922V | Missense Mutation (SNP) | VAF 16/413 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs1291884139; called by muse, mutect2
- SLFN14 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 22/344 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1463851112; called by muse, mutect2
- SLITRK3 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 176/766 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1490316717, COSV53852040; called by muse, mutect2, varscan2
- SMO | c.2302C>A p.P768T | Missense Mutation (SNP) | VAF 42/1340 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.077); catalogued as COSV50825620; called by muse, mutect2
- TNFAIP3 | c.2186G>C p.S729T | Missense Mutation (SNP) | VAF 28/630 reads (4%) | SIFT tolerated (0.9); PolyPhen benign (0.185); catalogued as COSV52797207; called by muse, mutect2
- TRAPPC5 | c.326A>G p.N109S | Missense Mutation (SNP) | VAF 243/823 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.091); catalogued as rs1202159236; called by muse, mutect2, varscan2
- WDR31 | c.1028G>T p.S343I (on ENST00000374193 / NM_001006615.3; = p.S342I on NM_145241.5) | Missense Mutation (SNP) | VAF 28/502 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100516734; called by muse, mutect2
- ZC3H13 | c.3035G>T p.G1012V | Missense Mutation (SNP) | VAF 32/506 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV54447724; called by muse, mutect2
- ACTR5 | c.545G>T p.S182I | Missense Mutation (SNP) | VAF 38/708 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); called by muse, mutect2
- ADAM12 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 71/231 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS19 | c.3373A>G p.T1125A | Missense Mutation (SNP) | VAF 14/445 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADPRHL1 | c.2305C>A p.P769T | Missense Mutation (SNP) | VAF 48/1102 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.055); called by muse, mutect2
- AFP | c.1778C>A p.A593D | Missense Mutation (SNP) | VAF 15/287 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.154); called by muse, mutect2
- AGO4 | c.1763C>T p.A588V | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- ANK3 | c.6646G>C p.V2216L | Missense Mutation (SNP) | VAF 28/554 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.012); called by muse, mutect2
- ANKRD18B | c.1256A>C p.H419P | Missense Mutation (SNP) | VAF 185/415 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- APBB1IP | c.1937G>C p.G646A | Missense Mutation (SNP) | VAF 33/718 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); called by muse, mutect2
- APOA4 | c.640C>A p.Q214K | Missense Mutation (SNP) | VAF 52/602 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.359); called by muse, mutect2
- ATP6V1A | c.969A>C p.R323S | Missense Mutation (SNP) | VAF 17/328 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP7A | c.1297G>A p.G433R | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- BCHE | c.1568G>A p.S523N | Missense Mutation (SNP) | VAF 17/649 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- BCL7C | c.554G>T p.R185I | Missense Mutation (SNP) | VAF 28/369 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2
- BIRC6 | c.8194A>G p.M2732V | Missense Mutation (SNP) | VAF 90/506 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- C1QTNF9 | c.667T>C p.F223L | Missense Mutation (SNP) | VAF 188/410 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- C1QTNF9B | c.667T>C p.F223L | Missense Mutation (SNP) | VAF 92/222 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- C2CD3 | c.6801C>G p.S2267R | Missense Mutation (SNP) | VAF 45/351 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1C | c.5718G>C p.E1906D (on ENST00000399634 / NM_001167625.1; = p.E1835D on NM_000719.7) | Missense Mutation (SNP) | VAF 109/534 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- CATSPER2 | c.996dup p.R333Sfs*11 | Frame Shift Ins (INS) | VAF 29/150 reads (19%) | called by mutect2, pindel, varscan2
- CCPG1 | c.1848T>A p.H616Q | Missense Mutation (SNP) | VAF 124/299 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH20 | c.2180T>C p.L727P | Missense Mutation (SNP) | VAF 30/594 reads (5%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.961); called by muse, mutect2
- CEP152 | c.740C>G p.A247G | Missense Mutation (SNP) | VAF 79/239 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTN6 | c.2990dup p.L997Ffs*12 | Frame Shift Ins (INS) | VAF 42/239 reads (18%) | called by mutect2, pindel, varscan2
- COPS3 | c.687A>T p.L229F | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CPAMD8 | c.392G>A p.G131E (on ENST00000651564; = p.G84E on NM_015692.5) | Missense Mutation (SNP) | VAF 32/406 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CR1 | c.3844G>T p.V1282L | Missense Mutation (SNP) | VAF 18/306 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2
- CREB3L2 | c.1284C>A p.N428K | Missense Mutation (SNP) | VAF 126/516 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CSDE1 | c.1753+1del p.X585_splice (on ENST00000358528 / NM_001007553.3; = p.X554_splice on NM_007158.6) | Splice Site (DEL) | VAF 125/365 reads (34%) | called by mutect2, pindel, varscan2
- CTBS | c.354C>A p.F118L | Missense Mutation (SNP) | VAF 88/227 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CTNNB1 | c.700T>G p.S234A | Missense Mutation (SNP) | VAF 14/399 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.111); called by muse, mutect2
- CUBN | c.6148C>G p.L2050V | Missense Mutation (SNP) | VAF 32/471 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- DCDC1 | c.4105G>T p.V1369F (on ENST00000597505 / NM_001367979.1; = p.V476F on NM_020869.3) | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.281); called by muse, mutect2
- DPYSL4 | c.1204G>C p.A402P | Missense Mutation (SNP) | VAF 30/640 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2
- DROSHA | c.2103G>C p.Q701H | Missense Mutation (SNP) | VAF 114/829 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- DYNC1I2 | c.1420G>A p.G474R | Missense Mutation (SNP) | VAF 31/571 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- ECI2 | c.590_607del p.S197_L202del (on ENST00000380118 / NM_206836.3; = p.S167_L172del on NM_006117.2) | In Frame Del (DEL) | VAF 48/305 reads (16%) | called by mutect2, pindel, varscan2
- EDN1 | c.390G>T p.R130S | Missense Mutation (SNP) | VAF 10/237 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.009); called by muse, mutect2
- EDNRB | c.461G>A p.R154Q (on ENST00000377211 / NM_001201397.1; = p.R64Q on NM_000115.5) | Missense Mutation (SNP) | VAF 32/742 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0.007); called by muse, mutect2
- EIF4G1 | c.4569G>C p.Q1523H (on ENST00000346169 / NM_198241.3; = p.Q1328H on NM_004953.5) | Missense Mutation (SNP) | VAF 40/812 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- EIF4G1 | c.4570G>T p.A1524S (on ENST00000346169 / NM_198241.3; = p.A1329S on NM_004953.5) | Missense Mutation (SNP) | VAF 42/804 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2
- ELP2 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 16/328 reads (5%) | called by muse, mutect2
- EPHA10 | c.892C>T p.L298F | Missense Mutation (SNP) | VAF 40/586 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.021); called by muse, mutect2
- F7 | c.572T>C p.V191A | Missense Mutation (SNP) | VAF 75/402 reads (19%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FAM20A | c.997C>A p.P333T | Missense Mutation (SNP) | VAF 32/670 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM71B | c.983A>G p.K328R | Missense Mutation (SNP) | VAF 33/870 reads (4%) | SIFT tolerated (0.56); PolyPhen benign (0.444); called by muse, mutect2
- FARP2 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 138/312 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FBN2 | c.3767A>T p.Q1256L | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- HNF1A | c.1204A>G p.N402D | Missense Mutation (SNP) | VAF 482/790 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); called by muse, varscan2
- JADE1 | c.2438A>G p.E813G | Missense Mutation (SNP) | VAF 151/367 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- MAB21L2 | c.305T>A p.L102Q | Missense Mutation (SNP) | VAF 46/483 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAMDC4 | c.2742_2762dup p.Q914_A920dup (on ENST00000445819; = p.Q835_A841dup on NM_206920.3) | In Frame Ins (INS) | VAF 106/452 reads (23%) | called by mutect2, varscan2
- MAP3K19 | c.429G>C p.L143F | Missense Mutation (SNP) | VAF 193/670 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- MAPKBP1 | c.2559A>T p.R853S (on ENST00000456763 / NM_001128608.2; = p.R847S on NM_014994.3) | Missense Mutation (SNP) | VAF 195/456 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- MBLAC1 | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 188/565 reads (33%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC5B | c.10810G>C p.A3604P | Missense Mutation (SNP) | VAF 43/928 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2
- NLRC3 | c.1148G>T p.S383I | Missense Mutation (SNP) | VAF 64/693 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.155); called by muse, mutect2
- NPAP1 | c.1582T>C p.S528P | Missense Mutation (SNP) | VAF 163/820 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.01); called by muse, varscan2
- NR3C1 | c.1640G>T p.G547V | Missense Mutation (SNP) | VAF 30/560 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NRAP | c.1724G>C p.G575A (on ENST00000359988 / NM_001322945.2; = p.G540A on NM_006175.4) | Missense Mutation (SNP) | VAF 37/544 reads (7%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.489); called by muse, mutect2
- OLIG1 | c.112T>A p.Y38N | Missense Mutation (SNP) | VAF 306/670 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.264); called by muse, varscan2
- OR2A2 | c.208A>G p.M70V | Missense Mutation (SNP) | VAF 71/732 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2
- PDIA3 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 30/630 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- PKIA | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 167/576 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PLCE1 | c.239T>C p.I80T | Missense Mutation (SNP) | VAF 232/430 reads (54%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPL | c.1331T>A p.I444N | Missense Mutation (SNP) | VAF 164/464 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R12C | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 27/1115 reads (2%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.726); called by muse, mutect2
- PRRC2A | c.5213C>G p.S1738* | Nonsense Mutation (SNP) | VAF 159/887 reads (18%) | called by muse, mutect2, varscan2
- PSG4 | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 131/401 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- PSME4 | c.2581C>T p.R861* | Nonsense Mutation (SNP) | VAF 78/339 reads (23%) | called by muse, mutect2, varscan2
- PTDSS1 | c.1207A>T p.I403F | Missense Mutation (SNP) | VAF 19/482 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2
- R3HDML | c.183A>T p.R61S | Missense Mutation (SNP) | VAF 233/915 reads (25%) | SIFT tolerated (0.94); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ROBO2 | c.1046A>G p.K349R | Missense Mutation (SNP) | VAF 101/213 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- RP1 | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 27/704 reads (4%) | called by muse, mutect2
- RTL3 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.784); called by muse, mutect2
- SHBG | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 18/537 reads (3%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.098); called by muse, mutect2
- SMYD1 | c.1103A>G p.E368G | Missense Mutation (SNP) | VAF 26/538 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2
- SPHKAP | c.1338G>T p.E446D | Missense Mutation (SNP) | VAF 106/421 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- STAT4 | c.670G>C p.D224H | Missense Mutation (SNP) | VAF 16/514 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); called by muse, mutect2
- SYNPR | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 132/349 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNRC18 | c.7366del p.E2456Rfs*44 | Frame Shift Del (DEL) | VAF 251/635 reads (40%) | called by mutect2, pindel, varscan2
- TNS3 | c.3257A>T p.Q1086L | Missense Mutation (SNP) | VAF 58/956 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.023); called by muse, mutect2
- TPR | c.6569G>T p.G2190V | Missense Mutation (SNP) | VAF 13/329 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TRABD2B | c.1282C>T p.H428Y | Missense Mutation (SNP) | VAF 68/826 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.03); called by muse, mutect2
- USP7 | c.2602T>C p.F868L | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2
- WDR31 | c.1027A>T p.S343C (on ENST00000374193 / NM_001006615.3; = p.S342C on NM_145241.5) | Missense Mutation (SNP) | VAF 27/498 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- ZNF510 | c.125C>G p.S42C | Missense Mutation (SNP) | VAF 36/318 reads (11%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.519); called by mutect2, varscan2
- ZP4 | c.1414T>C p.S472P | Missense Mutation (SNP) | VAF 123/359 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACACB | c.1144T>C p.L382= | Silent (SNP) | VAF 26/478 reads (5%) | catalogued as rs1465476093; called by muse, mutect2
- ATP2B4 | c.1989C>A p.T663= | Silent (SNP) | VAF 32/500 reads (6%) | called by muse, mutect2
- BRSK1 | c.2031G>A p.P677= | Silent (SNP) | VAF 239/510 reads (47%) | catalogued as rs755135302; called by muse, mutect2, varscan2
- CATSPER1 | c.1404C>A p.T468= | Silent (SNP) | VAF 111/420 reads (26%) | called by muse, mutect2, varscan2
- CCDC158 | c.423G>A p.E141= | Silent (SNP) | VAF 34/379 reads (9%) | catalogued as rs745891494, COSV66355488; called by muse, mutect2
- CHFR | c.237C>T p.T79= | Silent (SNP) | VAF 112/397 reads (28%) | called by muse, mutect2, varscan2
- CHPF2 | c.1260C>T p.P420= | Silent (SNP) | VAF 111/857 reads (13%) | called by muse, mutect2, varscan2
- COLEC11 | c.357C>G p.R119= | Silent (SNP) | VAF 39/574 reads (7%) | called by muse, mutect2
- CPLX2 | c.126G>A p.R42= | Silent (SNP) | VAF 207/705 reads (29%) | catalogued as rs773899228; called by muse, mutect2, varscan2
- CRACD | c.2400C>G p.V800= | Silent (SNP) | VAF 30/552 reads (5%) | catalogued as rs781498249; called by muse, mutect2
- EVI5L | c.276G>C p.R92= | Silent (SNP) | VAF 35/666 reads (5%) | catalogued as COSV54488029; called by muse, mutect2
- GABRB2 | c.1023A>G p.A341= | Silent (SNP) | VAF 143/487 reads (29%) | catalogued as rs1208154923, COSV99196692; called by muse, mutect2, varscan2
- GLIPR1L2 | c.84C>G p.L28= | Silent (SNP) | VAF 42/601 reads (7%) | called by muse, mutect2
- GOT1L1 | c.792G>C p.V264= | Silent (SNP) | VAF 121/497 reads (24%) | catalogued as rs750635428; called by muse, mutect2, varscan2
- HEPHL1 | c.1404C>T p.T468= | Silent (SNP) | VAF 19/665 reads (3%) | called by muse, mutect2
- HNRNPC | c.342G>A p.P114= | Silent (SNP) | VAF 108/262 reads (41%) | catalogued as rs751744618, COSV100193467; called by muse, mutect2, varscan2
- HNRNPCL1 | c.843G>A p.E281= | Silent (SNP) | VAF 16/496 reads (3%) | catalogued as rs1164255935; called by muse, mutect2
- HOXB8 | c.210G>A p.Q70= | Silent (SNP) | VAF 55/1040 reads (5%) | catalogued as COSV99493945; called by muse, mutect2
- IFT172 | c.3708T>C p.Y1236= | Silent (SNP) | VAF 149/424 reads (35%) | called by muse, mutect2, varscan2
- IL21R | c.996G>A p.T332= | Silent (SNP) | VAF 82/615 reads (13%) | catalogued as rs1244192788, COSV61970567, COSV61970979; called by muse, mutect2, varscan2
- MYBPC3 | c.1152C>T p.T384= | Silent (SNP) | VAF 180/552 reads (33%) | catalogued as rs775237084, COSV57022398, COSV57023784; called by muse, mutect2, varscan2
- NDUFV1 | c.480G>A p.G160= | Silent (SNP) | VAF 29/620 reads (5%) | catalogued as rs1294562179; called by muse, mutect2
- NGF | c.22C>T p.L8= | Silent (SNP) | VAF 11/326 reads (3%) | catalogued as COSV65687782; called by muse, mutect2
- NRDE2 | c.114C>T p.S38= | Silent (SNP) | VAF 140/356 reads (39%) | catalogued as COSV62964820, COSV62964904; called by muse, mutect2, varscan2
- OR5H15 | c.639T>A p.T213= | Silent (SNP) | VAF 26/386 reads (7%) | catalogued as rs530952227; called by muse, mutect2
- PDCD7 | c.882C>G p.L294= | Silent (SNP) | VAF 34/321 reads (11%) | called by muse, mutect2, varscan2
- RAPGEF3 | c.813C>T p.T271= (on ENST00000389212; = p.T229= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 127/297 reads (43%) | catalogued as rs1002833104, COSV99406021; called by muse, mutect2, varscan2
- RHPN1 | c.747C>T p.A249= | Silent (SNP) | VAF 135/456 reads (30%) | catalogued as rs941760356; called by muse, mutect2, varscan2
- RPS16 | c.318G>A p.K106= | Silent (SNP) | VAF 22/481 reads (5%) | called by muse, mutect2
- RSPH9 | c.738C>G p.G246= | Silent (SNP) | VAF 210/794 reads (26%) | catalogued as COSV64521962; called by muse, mutect2, varscan2
- SCAP | c.507C>T p.C169= | Silent (SNP) | VAF 131/380 reads (34%) | called by muse, mutect2, varscan2
- SPOPL | c.894A>T p.S298= | Silent (SNP) | VAF 44/648 reads (7%) | called by muse, mutect2
- TSTD1 | c.216T>C p.D72= | Silent (SNP) | VAF 173/653 reads (26%) | catalogued as rs1014937973; called by muse, mutect2, varscan2
- ZC3H6 | c.2853A>T p.G951= | Silent (SNP) | VAF 13/340 reads (4%) | called by muse, mutect2
- C5orf38 | c.*90T>A | 3'UTR (SNP) | VAF 51/1527 reads (3%) | called by muse, mutect2
- DBI | c.10-257T>A | Intron (SNP) | VAF 144/373 reads (39%) | called by muse, mutect2, varscan2
- RGR | c.370+1383A>G | Intron (SNP) | VAF 28/470 reads (6%) | called by muse, mutect2
- RGS3 | c.3081-490C>T | Intron (SNP) | VAF 44/331 reads (13%) | called by muse, mutect2, varscan2
- SLC6A1 | c.1192-10C>T | Intron (SNP) | VAF 42/546 reads (8%) | called by muse, mutect2
